Somatic mutation profile of tumor specimen TCGA-S9-A7QZ-01A (aliquot TCGA-S9-A7QZ-01A-12D-A34J-08) from TCGA case TCGA-S9-A7QZ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 41.9 years (15,300 days).
Specimen TCGA-S9-A7QZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e6b8d3b-b7d4-4793-8b85-9e62e7193844.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7QZ-10A (Blood Derived Normal), aliquot TCGA-S9-A7QZ-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7ae4d17-6d22-4525-aac4-5defd5316b66

The open-access MAF lists 54 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 11, Frame Shift Del 9, In Frame Del 9, 3'UTR 1, Splice Site 1, Nonsense Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 47/126 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- LAMP2 | c.851_852del p.F284Cfs*7 | Frame Shift Del (DEL) | VAF 16/115 reads (14%) | catalogued as rs727504648; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.572_574del p.P191del | In Frame Del (DEL) | VAF 10/63 reads (16%) | hotspot (GDC flag); catalogued as rs1555525902; called by pindel, varscan2
- ADCY9 | c.1057_1059del p.E353del | In Frame Del (DEL) | VAF 34/156 reads (22%) | catalogued as rs751868048; called by pindel, varscan2
- AKNA | c.3722G>C p.C1241S | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99800162; called by muse, mutect2
- ATP13A5 | c.3226+1_3226+2del p.X1076_splice | Splice Site (DEL) | VAF 8/51 reads (16%) | catalogued as rs771969729; called by mutect2, pindel, varscan2
- ATP1B1 | c.902_906del p.V301Efs*11 | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | catalogued as rs1462515035; called by mutect2, pindel, varscan2
- ATR | c.968A>G p.E323G | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100638074; called by muse, mutect2
- B9D1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs778260923, COSV52069693; called by muse, mutect2, varscan2
- CCDC3 | c.667_669del p.K223del | In Frame Del (DEL) | VAF 31/196 reads (16%) | catalogued as rs777338842; called by pindel, varscan2
- CENPE | c.4679A>G p.K1560R | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.84); catalogued as COSV99477635; called by muse, mutect2, varscan2
- CEP192 | c.6332_6334del p.P2111del | In Frame Del (DEL) | VAF 30/192 reads (16%) | catalogued as rs1244255913; called by pindel, varscan2
- CEP83 | c.194A>T p.K65M | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100352803; called by muse, mutect2, varscan2
- CYP4F11 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs145564844; called by muse, mutect2, varscan2
- EIF4A1 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 33/277 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV53442198, COSV99548884; called by muse, mutect2, varscan2
- GHR | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV100050449; called by muse, mutect2, varscan2
- INTS7 | c.2455A>T p.I819F | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100877473; called by muse, mutect2, varscan2
- MDH1B | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV100982171; called by muse, mutect2, varscan2
- MGA | c.3098C>T p.T1033I | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV99579521; called by muse, mutect2, varscan2
- MIER2 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs758044102, COSV53393898; called by muse, mutect2, varscan2
- NECAP2 | c.23C>G p.S8W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59188115, COSV59188823; called by muse, mutect2, varscan2
- OGDH | c.2173G>A p.V725M | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99758671; called by muse, mutect2, varscan2
- OR6C2 | c.635T>C p.V212A | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100498681; called by muse, mutect2, varscan2
- PKHD1L1 | c.5376G>C p.E1792D | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101005974, COSV65753625; called by muse, mutect2
- PRKDC | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as rs769059077, COSV100040008; called by muse, mutect2, varscan2
- RESF1 | c.2779_2781del p.S927del | In Frame Del (DEL) | VAF 19/85 reads (22%) | catalogued as rs757259507; called by mutect2, pindel, varscan2
- SLC4A5 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs1207390221, COSV100697583, COSV100698202; called by muse, mutect2
- STC1 | c.490G>T p.V164F | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV51688206, COSV99282444; called by muse, mutect2
- TXNDC11 | c.2497_2500del p.E833Sfs*4 (on ENST00000356957 / NM_001303447.2; = p.E806Sfs*4 on NM_015914.7 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as rs1216090468; called by mutect2, pindel, varscan2
- UGT2B17 | c.1579A>T p.K527* | Nonsense Mutation (SNP) | VAF 40/126 reads (32%) | catalogued as COSV100497203; called by muse, mutect2, varscan2
- ZBTB34 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.956); catalogued as COSV100043682; called by muse, mutect2, varscan2
- ACTRT1 | c.1006_1009del p.R336Afs*11 | Frame Shift Del (DEL) | VAF 27/67 reads (40%) | called by mutect2, pindel, varscan2
- ANKAR | c.572_573del p.K191Rfs*7 | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | called by mutect2, pindel, varscan2
- AP3D1 | c.2641_2643del p.K881del | In Frame Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- CIC | c.3020_3021del p.V1007Afs*143 | Frame Shift Del (DEL) | VAF 30/89 reads (34%) | called by pindel, varscan2
- COL12A1 | c.2951_2953del p.G984del | In Frame Del (DEL) | VAF 32/149 reads (21%) | called by mutect2, pindel, varscan2
- CUBN | c.5339_5340del p.F1780Yfs*20 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | called by mutect2, pindel, varscan2
- FUBP1 | c.782del p.F261Sfs*12 | Frame Shift Del (DEL) | VAF 18/115 reads (16%) | called by mutect2, pindel, varscan2
- PCDHB13 | c.1663_1665del p.N555del | In Frame Del (DEL) | VAF 24/135 reads (18%) | called by mutect2, pindel, varscan2
- RTF1 | c.508_509del p.D170Lfs*6 | Frame Shift Del (DEL) | VAF 46/211 reads (22%) | called by mutect2, pindel, varscan2
- TRMT10C | c.229_231del p.E77del | In Frame Del (DEL) | VAF 20/151 reads (13%) | called by pindel, varscan2
- ZNF668 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.767); called by muse, mutect2
- C15orf39 | c.192G>A p.A64= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs777215863, COSV100641402, COSV62297184; called by muse, mutect2, varscan2
- CACNA1S | c.5131C>T p.L1711= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100754911; called by muse, mutect2, varscan2
- CAPZA3 | c.9T>A p.L3= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as COSV99856223; called by muse, mutect2, varscan2
- CLCA1 | c.1629A>T p.V543= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV99322231; called by muse, mutect2, varscan2
- CTNND1 | c.660T>C p.G220= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as COSV100650004; called by muse, mutect2, varscan2
- DAAM1 | c.1644C>A p.L548= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as COSV100658322; called by muse, mutect2, varscan2
- MYO1C | c.717C>A p.I239= (on ENST00000648651 / NM_001080779.2; = p.I204= on NM_033375.5) | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV100704313; called by muse, mutect2, varscan2
- OR10H1 | c.423C>T p.C141= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as rs746108480, COSV100612409; called by muse, mutect2
- SLC20A1 | c.1815A>G p.A605= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as rs545904103, COSV99734006; called by muse, mutect2, varscan2
- SLC49A4 | c.1080A>G p.S360= | Silent (SNP) | VAF 46/143 reads (32%) | catalogued as COSV99658984; called by muse, mutect2, varscan2
- TNFSF14 | c.636G>A p.G212= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV99838399, COSV99838434; called by muse, mutect2
- SLC35A3 | c.*449G>A | 3'UTR (SNP) | VAF 25/49 reads (51%) | catalogued as COSV100924658; called by muse, mutect2, varscan2
